Somatic mutation profile of tumor specimen TCGA-RP-A6K9-06A (aliquot TCGA-RP-A6K9-06A-41D-A34U-08) from TCGA case TCGA-RP-A6K9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-RP-A6K9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff5a2a1-5be3-4557-8faf-ec677be406d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RP-A6K9-10A (Blood Derived Normal), aliquot TCGA-RP-A6K9-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb155a0a-bb96-4c63-a846-104930034924

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, RNA 2, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC12A3 | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs145337602, CM088290, CM981831; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARHGAP30 | c.3221A>G p.Q1074R (on ENST00000368013 / NM_001025598.2; = p.Q863R on NM_181720.3) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV100920123, COSV100920560; called by muse, mutect2, varscan2
- BRD4 | c.1842G>C p.E614D | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99649759; called by muse, mutect2
- CACNA2D1 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100665493; called by muse, mutect2, varscan2
- CACNB3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775655875, COSV99974595; called by muse, mutect2, varscan2
- CAMSAP1 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs764159651, COSV100409518, COSV56728343; called by muse, mutect2, varscan2
- CERT1 | c.925T>C p.Y309H (on ENST00000405807 / NM_001130105.1; = p.Y181H on NM_005713.3) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV54663596; called by muse, mutect2, varscan2
- CHAF1A | c.1376A>T p.K459M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100010755; called by muse, mutect2, varscan2
- CHAF1A | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs769265139, COSV100010758; called by muse, mutect2, varscan2
- CHAF1B | c.35A>G p.N12S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1179175301, COSV100023308; called by muse, mutect2
- CMTR1 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100990842; called by muse, mutect2
- DNTT | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as rs775435496, COSV64522899; called by muse, mutect2, varscan2
- DOP1A | c.4156T>C p.S1386P | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99380720; called by muse, mutect2, varscan2
- DYNC1H1 | c.11927A>C p.E3976A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV100794276; called by muse, mutect2, varscan2
- ELOC | c.195A>G p.I65M | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53023288; called by muse, mutect2
- EPS15 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1454060750, COSV100869388; called by muse, mutect2, varscan2
- GABRA1 | c.1237T>A p.F413I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV99195682; called by muse, mutect2, varscan2
- HORMAD1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100463759; called by muse, mutect2, varscan2
- IVNS1ABP | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100832486; called by muse, mutect2
- KCNT2 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs200217178; called by muse, mutect2, varscan2
- LAMA3 | c.5150G>A p.R1717H (on ENST00000313654 / NM_198129.4; = p.R108H on NM_000227.6) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs754903702, COSV52535546; called by muse, varscan2
- LARP4B | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100294987, COSV60223794; called by muse, mutect2
- MAP1A | c.4019T>C p.I1340T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as COSV100287965; called by muse, mutect2, varscan2
- METTL3 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99397980; called by muse, mutect2
- MYO1A | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270490; called by muse, mutect2, varscan2
- PCDHA8 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65327530; called by muse, mutect2, varscan2
- PCDHGB6 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV53942275; called by muse, mutect2, varscan2
- PHYKPL | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100359139; called by muse, mutect2, varscan2
- PLCG2 | c.3101C>T p.T1034M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs563473638, COSV100842025; called by muse, mutect2, varscan2
- PRTG | c.3093G>T p.K1031N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101221182; called by muse, mutect2, varscan2
- PXDNL | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs776683885, COSV62494746; called by muse, mutect2
- RBL1 | c.2382G>A p.K794= | Splice Region (SNP) | VAF 25/149 reads (17%) | catalogued as COSV100726844, COSV60331526; called by muse, mutect2, varscan2
- RGS12 | c.2962C>G p.L988V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122486; called by muse, mutect2, varscan2
- SLBP | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100571328; called by muse, mutect2, varscan2
- SLC16A2 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1177004258, COSV99330307; called by muse, mutect2
- SPATA7 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV99247656; called by muse, mutect2
- SVEP1 | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65687333; called by muse, mutect2
- TBC1D31 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99782280; called by muse, mutect2
- ZIM2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV55624495, COSV55650701, COSV99686891; called by muse, mutect2, varscan2
- ZNF804A | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100166037, COSV56454542; called by muse, mutect2, varscan2
- ZSWIM8 | c.5437C>A p.Q1813K (on ENST00000605216 / NM_001242487.2; = p.Q1818K on NM_015037.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100013551; called by muse, mutect2
- BAP1 | c.560_580+13del p.X187_splice | Splice Site (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- GNAT3 | c.699C>A p.V233= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV68069696; called by muse, mutect2, varscan2
- KIAA0319 | c.1212C>T p.V404= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs757441883, COSV100985131; called by muse, mutect2
- MACROD2 | c.393A>G p.T131= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs895583940, COSV99425943; called by muse, mutect2, varscan2
- MCU | c.342A>G p.Q114= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs575231925, COSV100849053; called by muse, mutect2, varscan2
- MUC4 | c.2718G>C p.R906= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100638940; called by muse, mutect2, varscan2
- NLRP5 | c.1980G>T p.G660= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV101173315, COSV66763775, COSV66764886; called by muse, mutect2, varscan2
- OR51M1 | c.228C>A p.S76= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV60784184, COSV60785607; called by muse, mutect2, varscan2
- PCDHA2 | c.825C>T p.S275= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs782729838, COSV100973462; called by muse, mutect2, varscan2
- SFI1 | c.276C>T p.A92= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV101191878; called by muse, mutect2
- WDR13 | c.1389C>T p.C463= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1423386867, COSV99489050; called by muse, mutect2, varscan2
- ZNF214 | c.513A>T p.I171= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV99547103; called by muse, mutect2, varscan2
- ZNF771 | c.468C>T p.F156= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100075167; called by muse, mutect2, varscan2
- HERC2P3 | n.1638C>T | RNA (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- MIR221 | n.81G>T | RNA (SNP) | VAF 10/75 reads (13%) | called by mutect2, varscan2
